Somatic mutation profile of tumor specimen TCGA-BA-6872-01A (aliquot TCGA-BA-6872-01A-11D-1870-08) from TCGA case TCGA-BA-6872, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; Tumor grade: G2; Age at diagnosis: 47.4 years (17,296 days).
Specimen TCGA-BA-6872-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70c3c5e4-22a0-4927-a7de-0daf70a9b695.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-6872-10A (Blood Derived Normal), aliquot TCGA-BA-6872-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb18dfdd-09fd-47d1-90b5-eb380e74993f

The open-access MAF lists 167 somatic variants for this specimen: 142 protein-altering or splice-affecting, 25 silent.
By variant classification: Missense Mutation 119, Silent 25, Nonsense Mutation 6, Frame Shift Del 6, Splice Site 4, Frame Shift Ins 3, Splice Region 2, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.387C>A p.Y129* | Nonsense Mutation (SNP) | VAF 22/35 reads (63%) | hotspot (GDC flag); catalogued as COSV58684005, COSV58689871; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 35/61 reads (57%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AAAS | c.652C>T p.L218F | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99267105; called by muse, mutect2, varscan2
- ABCA12 | c.3772C>A p.L1258I (on ENST00000272895 / NM_173076.3; = p.L940I on NM_015657.3) | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99791657; called by muse, mutect2
- ACACA | c.3737A>G p.Y1246C | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.818); catalogued as rs749437417; called by muse, mutect2, varscan2
- ACSM5 | c.1207-1G>A p.X403_splice | Splice Site (SNP) | VAF 24/131 reads (18%) | catalogued as COSV100089460; called by muse, mutect2, varscan2
- ADGRE3 | c.1886C>T p.S629F | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as COSV53730133; called by muse, mutect2, varscan2
- ADGRL2 | c.1241T>G p.F414C | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99591183; called by muse, mutect2, varscan2
- ADPRM | c.223A>G p.I75V | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs761104737, COSV101126100; called by muse, mutect2, varscan2
- ALB | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as COSV99892093; called by muse, mutect2, varscan2
- ALOX12 | c.296G>A p.W99* | Nonsense Mutation (SNP) | VAF 5/8 reads (63%) | catalogued as COSV99278404; called by muse, mutect2, varscan2
- ANAPC7 | c.278A>G p.Y93C | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV101484807; called by muse, mutect2, varscan2
- APPL2 | c.874C>G p.L292V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99315075; called by muse, mutect2, varscan2
- ASCC1 | c.955+1G>C p.X319_splice (on ENST00000342444 / NM_001369085.1; = p.X291_splice on NM_001198798.2 and 8 other RefSeq transcripts) | Splice Site (SNP) | VAF 11/102 reads (11%) | catalogued as COSV100403707; called by muse, mutect2, varscan2
- B4GALT5 | c.251A>G p.D84G | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as COSV100867117; called by muse, mutect2, varscan2
- BLOC1S6 | c.195G>C p.Q65H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as COSV99593527; called by muse, mutect2, varscan2
- BRCA1 | c.2557G>A p.D853N | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100524898; called by muse, mutect2, varscan2
- BTAF1 | c.1784C>T p.S595L | Missense Mutation (SNP) | VAF 40/257 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.175); catalogued as COSV99795726; called by muse, mutect2, varscan2
- C12orf42 | c.971C>A p.S324Y | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV59390964; called by muse, mutect2, varscan2
- CATSPER1 | c.691C>T p.H231Y | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV100376206; called by muse, mutect2, varscan2
- CC2D2A | c.4099_4101del p.E1367del | In Frame Del (DEL) | VAF 9/58 reads (16%) | catalogued as rs794729225; called by pindel, varscan2
- CCDC110 | c.1594C>G p.L532V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV100294137; called by muse, mutect2, varscan2
- CCDC144A | c.872T>C p.L291S | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.089); catalogued as COSV100138667; called by muse, mutect2, varscan2
- CCNG1 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.713); catalogued as COSV100546773; called by muse, mutect2, varscan2
- CD14 | c.207T>A p.F69L | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100117642; called by muse, mutect2
- CD1A | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56862255, COSV99192614; called by muse, mutect2, varscan2
- CDKL5 | c.2540C>T p.S847L | Missense Mutation (SNP) | VAF 71/176 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.196); catalogued as rs755573510, COSV66112141; called by muse, mutect2, varscan2
- CLCN1 | c.774G>C p.E258D | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as COSV100578458; called by muse, mutect2, varscan2
- CSMD3 | c.10336G>A p.G3446S (on ENST00000297405 / NM_001363185.1; = p.G3277S on NM_052900.3) | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99845724, COSV99847239; called by muse, mutect2
- DDB1 | c.2053G>A p.D685N | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV100074825; called by muse, mutect2, varscan2
- DENND4A | c.4118A>G p.D1373G | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV101475416; called by muse, mutect2, varscan2
- DLG5 | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100967821; called by muse, mutect2, varscan2
- DNAH5 | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as COSV99453394; called by muse, mutect2, varscan2
- DOT1L | c.1163A>T p.K388M | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101288797; called by muse, mutect2, varscan2
- DST | c.15031G>T p.V5011L (on ENST00000361203 / NM_001374722.1; = p.V2599L on NM_015548.5) | Missense Mutation (SNP) | VAF 98/321 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.023); catalogued as COSV55008421, COSV99759325; called by muse, mutect2, varscan2
- EGFR | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 72/932 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99294544; called by muse, mutect2
- EPC2 | c.354T>G p.D118E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV99310118; called by muse, mutect2, varscan2
- FAAP24 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1436868159, COSV54289517; called by muse, mutect2, varscan2
- FAM155A | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs867560423, COSV65562295; called by muse, mutect2, varscan2
- FAR1 | c.1046A>G p.Y349C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.325); catalogued as COSV100701648; called by muse, mutect2, varscan2
- FHOD3 | c.270C>T p.A90= | Splice Region (SNP) | VAF 18/32 reads (56%) | catalogued as rs771131930, COSV57178198, COSV99942615; called by muse, mutect2, varscan2
- FOSL2 | c.118A>G p.M40V | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV99268504; called by muse, mutect2, varscan2
- FRA10AC1 | c.309G>C p.K103N | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100784743; called by muse, mutect2, varscan2
- FTMT | c.504G>C p.K168N | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs568437715, COSV100360436, COSV58419583; called by muse, mutect2, varscan2
- GABRQ | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 219/290 reads (76%) | catalogued as COSV100941416; called by muse, mutect2, varscan2
- GOLM2 | c.830C>G p.S277C | Missense Mutation (SNP) | VAF 78/159 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV55462785, COSV55466529; called by muse, mutect2, varscan2
- GP1BA | c.684G>C p.E228D | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV99851167; called by muse, mutect2, varscan2
- GRM1 | c.572A>T p.D191V | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99268588; called by muse, mutect2, varscan2
- HMGCLL1 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.646); catalogued as rs772259012, COSV51441906; called by muse, mutect2
- HSPA4 | c.2491G>T p.D831Y | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs144576995, COSV59181726; called by muse, mutect2, varscan2
- IGHG2 | c.524T>A p.F175Y | Missense Mutation (SNP) | VAF 93/322 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs373951106; called by muse, mutect2, varscan2
- IL12RB2 | c.530A>C p.Y177S | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.089); catalogued as COSV99255592; called by muse, mutect2, varscan2
- INTS12 | c.851del p.S284Cfs*3 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | catalogued as COSV100415809; called by mutect2, pindel, varscan2
- JAK1 | c.3370-1G>A p.X1124_splice | Splice Site (SNP) | VAF 15/69 reads (22%) | catalogued as COSV53806417; called by muse, mutect2
- JUP | c.2194G>A p.G732S | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.015); catalogued as rs781885294, COSV100159779; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KBTBD3 | c.1045G>A p.G349S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101595721; called by muse, mutect2, varscan2
- KRT25 | c.981G>C p.L327F | Missense Mutation (SNP) | VAF 20/271 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100380037; called by muse, mutect2
- KSR2 | c.2605G>A p.A869T | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.371); catalogued as rs757146540, COSV100196512; called by muse, mutect2, varscan2
- LBP | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.059); catalogued as COSV99461230; called by muse, mutect2, varscan2
- LEPR | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.576); catalogued as rs1447617648, COSV100756731; called by muse, mutect2, varscan2
- LRP2 | c.6442C>T p.R2148W | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774074912, COSV55573498; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LUC7L3 | c.515T>C p.L172P | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1567874334, COSV99537152; called by muse, mutect2, varscan2
- MBOAT7 | c.1327C>A p.L443M | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.652); catalogued as rs1206488099, COSV99825002; called by muse, mutect2, varscan2
- MCM6 | c.1502C>A p.A501E | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51468398; called by muse, mutect2, varscan2
- MICU3 | c.1195A>G p.T399A | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1286936671, COSV100536531; called by muse, mutect2, varscan2
- MMP16 | c.1017A>C p.K339N | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.536); catalogued as COSV99690093; called by muse, mutect2, varscan2
- MSH4 | c.509A>G p.E170G | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99592412; called by muse, mutect2, varscan2
- MUC5B | c.14821A>G p.T4941A | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV101500692; called by muse, mutect2, varscan2
- MYH8 | c.3949G>A p.E1317K | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs1164868270, COSV101238683; called by muse, mutect2, varscan2
- NCKAP1 | c.1001A>G p.H334R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.534); catalogued as COSV100720534; called by muse, mutect2, varscan2
- NKTR | c.3334G>A p.E1112K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.051); catalogued as rs761052283, COSV99236254; called by muse, mutect2, varscan2
- NRXN1 | c.822T>C p.G274= | Splice Region (SNP) | VAF 7/24 reads (29%) | catalogued as COSV101279935; called by muse, mutect2, varscan2
- NUAK2 | c.1655A>T p.E552V | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100904145; called by muse, mutect2, varscan2
- NUAK2 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs970229455, COSV100904146; called by muse, mutect2, varscan2
- NUDT1 | c.533C>T p.T178M (on ENST00000397048 / NM_198952.1; = p.T155M on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.188); catalogued as rs746490760, COSV56127286; called by muse, mutect2, varscan2
- NUP62 | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs748844929, COSV100352305; called by muse, mutect2, varscan2
- NXPE3 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.223); catalogued as rs139375291; called by muse, mutect2, varscan2
- OR6N1 | c.638T>G p.L213R | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV100625284; called by muse, mutect2
- OSBP | c.624G>C p.Q208H | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.028); catalogued as rs568879919, COSV99803342; called by muse, mutect2
- OSBPL6 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 23/365 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV99508389; called by muse, mutect2
- PAK5 | c.744G>C p.E248D | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.01); catalogued as rs1192887616, COSV100781643, COSV100781763; called by muse, mutect2, varscan2
- PALB2 | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as rs587781954, COSV99848923; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PCDH11X | c.1889C>A p.S630* | Nonsense Mutation (SNP) | VAF 14/24 reads (58%) | catalogued as COSV100014716, COSV100015525, COSV53472507; called by muse, mutect2, varscan2
- PCNT | c.2524G>C p.E842Q | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV64025049, COSV64025882, COSV64029451; called by muse, mutect2
- PDE12 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs753112140, COSV100239951; called by muse, mutect2, varscan2
- PEG3 | c.2376T>G p.S792R | Missense Mutation (SNP) | VAF 81/181 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.361); catalogued as COSV99690177; called by muse, mutect2, varscan2
- PIWIL4 | c.1985T>C p.V662A | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV100133394; called by muse, mutect2, varscan2
- PLCG2 | c.2414del p.G805Afs*31 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as COSV100842693, COSV63875044; called by mutect2, pindel, varscan2
- PLEKHA7 | c.2567C>G p.S856* | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | catalogued as COSV100261994; called by muse, mutect2, varscan2
- PLEKHG1 | c.157A>C p.K53Q | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as COSV100651843; called by muse, mutect2, varscan2
- PPARGC1B | c.1945G>A p.G649R | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs1450705357, COSV100495105; called by muse, mutect2, varscan2
- PRDM4 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV99946709; called by muse, mutect2
- PRKCQ | c.2056A>G p.M686V | Missense Mutation (SNP) | VAF 130/230 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99577709; called by muse, mutect2, varscan2
- PROCR | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.055); catalogued as COSV99405736; called by muse, mutect2, varscan2
- PROX1 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV54780929, COSV99800120; called by muse, mutect2, varscan2
- PRPF6 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV53870126, COSV99412699; called by muse, mutect2, varscan2
- RGS5 | c.324G>C p.K108N | Missense Mutation (SNP) | VAF 65/360 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as COSV100009332; called by muse, mutect2, varscan2
- RMND1 | c.71G>T p.R24I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.364); catalogued as COSV100323796; called by muse, mutect2
- RNF14 | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV100641284; called by muse, mutect2
- ROBO4 | c.2140C>T p.L714F | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100127824; called by muse, mutect2, varscan2
- RRAGD | c.401T>A p.I134N | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100784643; called by muse, mutect2, varscan2
- RTN4 | c.2653T>G p.L885V | Missense Mutation (SNP) | VAF 39/60 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as rs1388779293, COSV100463842; called by muse, mutect2, varscan2
- SEMA6A | c.2851C>A p.Q951K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.127); catalogued as COSV99145924; called by muse, mutect2, varscan2
- SMAD2 | c.1193T>C p.V398A | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100054002; called by muse, mutect2, varscan2
- SMC1B | c.3484A>T p.N1162Y | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100663465; called by muse, mutect2, varscan2
- SMURF2 | c.526C>G p.L176V | Missense Mutation (SNP) | VAF 5/108 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs933502943, COSV99301026; called by muse, mutect2
- SORCS1 | c.1823G>A p.R608Q | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs201674495, COSV53840707; called by muse, mutect2, varscan2
- SPRR1A | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.191); catalogued as rs865995231, COSV100201103; called by muse, mutect2, varscan2
- STBD1 | c.1058C>A p.A353E | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs527950885, COSV99421694; called by muse, mutect2, varscan2
- SUGCT | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as COSV100004241; called by muse, mutect2
- SUPT6H | c.3454A>G p.M1152V | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs753388807, COSV100112734; called by muse, mutect2, varscan2
- TBX19 | c.424T>C p.F142L | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100892399; called by muse, mutect2, varscan2
- TMEM119 | c.218C>T p.T73I | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV101219540; called by muse, mutect2, varscan2
- TRHDE | c.2291T>C p.L764P | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53866190; called by muse, mutect2, varscan2
- TRHDE | c.2474G>T p.G825V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1253348768, COSV99672207; called by muse, varscan2
- TRIM10 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs768234023, COSV100939598; called by muse, mutect2, varscan2
- TRIP12 | c.1298G>A p.S433N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as COSV99390854; called by muse, mutect2, varscan2
- TRMT12 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV100149285; called by muse, mutect2, varscan2
- TTN | c.93884G>A p.R31295H (on ENST00000591111; = p.R23871H on NM_003319.4) | Missense Mutation (SNP) | VAF 17/139 reads (12%) | PolyPhen probably damaging (0.998); catalogued as rs774296358, COSV60462824; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.32705C>T p.P10902L (on ENST00000591111; = p.P9975L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | PolyPhen benign (0.154); catalogued as rs757268986, COSV59976511, COSV60422857; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBXN2A | c.61G>C p.D21H | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV100465273; called by muse, mutect2
- UNC13C | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs746269797, COSV52862396; called by muse, mutect2, varscan2
- UROS | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV100908905, COSV64223745; called by muse, mutect2
- VPS13C | c.10505G>C p.R3502T (on ENST00000644861 / NM_020821.3; = p.R3459T on NM_017684.5) | Missense Mutation (SNP) | VAF 51/225 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99829925; called by muse, mutect2, varscan2
- VPS29 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV100804911; called by muse, mutect2, varscan2
- XIRP2 | c.3382G>T p.E1128* (on ENST00000628543; = p.E1303* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 17/85 reads (20%) | catalogued as COSV54679925, COSV54703695; called by muse, mutect2, varscan2
- ZBTB21 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as COSV100177348; called by muse, mutect2, varscan2
- ZBTB38 | c.196A>G p.T66A | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV100375963; called by muse, mutect2, varscan2
- ZNF347 | c.194A>G p.E65G | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100498408; called by muse, mutect2, varscan2
- ZNF577 | c.463G>C p.G155R | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV56816903; called by muse, mutect2
- DLGAP4 | c.2647_2681del p.G883Yfs*7 (on ENST00000339266 / NM_001365621.1; = p.G880Yfs*7 on NM_014902.6) | Frame Shift Del (DEL) | VAF 59/142 reads (42%) | called by mutect2, pindel
- GABRG1 | c.1135A>T p.T379S | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- HEXIM1 | c.185_188del p.E62Gfs*23 | Frame Shift Del (DEL) | VAF 7/48 reads (15%) | called by mutect2, pindel, varscan2
- IQGAP1 | c.110dup p.N38Efs*5 | Frame Shift Ins (INS) | VAF 15/71 reads (21%) | called by mutect2, varscan2
- IQGAP1 | c.111delinsAT p.N38* | Frame Shift Ins (INS) | VAF 19/91 reads (21%) | called by mutect2*, pindel, varscan2*
- MAP1A | c.2049dup p.H684Tfs*29 | Frame Shift Ins (INS) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- PCDH15 | c.1154_1166del p.I385Tfs*32 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel, varscan2
- POTEA | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SPATA31A1 | c.3545C>T p.P1182L | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SRRD | c.764+3_764+6del p.X255_splice | Splice Site (DEL) | VAF 7/35 reads (20%) | called by mutect2, pindel
- STC1 | c.534del p.R179Efs*4 | Frame Shift Del (DEL) | VAF 41/98 reads (42%) | called by mutect2, pindel, varscan2
- ZNF320 | c.840_848del p.K280_A283delinsN | In Frame Del (DEL) | VAF 19/103 reads (18%) | called by mutect2, pindel, varscan2
- AASS | c.1626C>T p.F542= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV62789737; called by muse, mutect2, varscan2
- ADGRL2 | c.1446A>T p.T482= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV99591186; called by muse, mutect2, varscan2
- AP3D1 | c.1209C>T p.I403= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV100642990; called by muse, mutect2, varscan2
- ATP4A | c.720C>T p.P240= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as rs776127328, COSV52866834, COSV99383005; called by muse, mutect2, varscan2
- C12orf43 | c.552G>A p.E184= | Silent (SNP) | VAF 40/188 reads (21%) | catalogued as rs1396267838, COSV99982944; called by muse, mutect2, varscan2
- CABIN1 | c.2227C>T p.L743= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99573894; called by muse, mutect2, varscan2
- CASQ1 | c.771G>A p.E257= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV100927359; called by muse, mutect2, varscan2
- CLEC18C | c.345G>A p.A115= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs764471871, COSV100032230; called by mutect2, varscan2
- CSMD3 | c.8187T>C p.Y2729= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV99845727; called by muse, mutect2, varscan2
- DIRAS1 | c.39C>T p.F13= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs756529032, COSV60216602; called by muse, mutect2, varscan2
- DNTT | c.303C>A p.L101= | Silent (SNP) | VAF 54/168 reads (32%) | catalogued as COSV100960728; called by muse, mutect2, varscan2
- FOXI1 | c.1053T>A p.S351= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV100089556; called by muse, mutect2, varscan2
- GC | c.103C>T p.L35= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV99910109; called by muse, mutect2
- GTPBP6 | c.870G>A p.T290= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs368301170, COSV100397824; called by muse, mutect2, varscan2
- KIF5C | c.2811G>A p.T937= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs922422808, COSV101276193, COSV68479844; called by muse, mutect2, varscan2
- KRTAP10-9 | c.603C>G p.V201= | Silent (SNP) | VAF 80/408 reads (20%) | catalogued as COSV100555279; called by muse, mutect2, varscan2
- LEFTY1 | c.918C>T p.F306= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99686615; called by muse, mutect2, varscan2
- MICAL3 | c.4191G>A p.E1397= | Silent (SNP) | VAF 37/216 reads (17%) | catalogued as rs764428773, COSV101490949; called by muse, mutect2, varscan2
- RBL1 | c.222G>A p.T74= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as rs573841274, COSV100726872; called by muse, mutect2, varscan2
- SC5D | c.171C>G p.V57= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV99873197; called by muse, mutect2, varscan2
- SCN1A | c.5718C>T p.I1906= (on ENST00000303395 / NM_001202435.3; = p.I1895= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as COSV100321810; called by muse, mutect2
- SH2D4B | c.276C>T p.Y92= | Silent (SNP) | VAF 41/146 reads (28%) | catalogued as rs149783849; called by muse, mutect2, varscan2
- STARD5 | c.198C>T p.D66= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV100250917; called by muse, mutect2, varscan2
- TRANK1 | c.6954C>G p.L2318= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV100084509, COSV57143690; called by muse, mutect2
- ZNF26 | c.891G>A p.L297= | Silent (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
